Somatic mutation profile of tumor specimen TARGET-20-PATKKI-04A (aliquot TARGET-20-PATKKI-04A-01D) from TARGET case TARGET-20-PATKKI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,238 days).
Specimen TARGET-20-PATKKI-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 124d7e69-cd13-4edc-97fc-fbebbe120433.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATKKI-14A (Bone Marrow Normal), aliquot TARGET-20-PATKKI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5149b133-5ed4-44b9-9498-b5f608ad091a

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC168 | c.14155A>G p.T4719A | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1214226268; called by muse, mutect2, varscan2
- COL12A1 | c.6199A>G p.I2067V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs376192452; called by mutect2, varscan2
- DOCK8 | c.5258A>G p.K1753R | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs771651682; called by mutect2, varscan2
- WT1 | c.1101_1102dup p.R368Hfs*70 | Frame Shift Ins (INS) | VAF 28/97 reads (29%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by mutect2, pindel, varscan2
- AHNAK | c.10968C>T p.G3656= | Silent (SNP) | VAF 44/287 reads (15%) | catalogued as rs199514616; called by muse, mutect2, varscan2
- EP400 | c.8031C>T p.A2677= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs4075351; called by mutect2, varscan2
- FLNB | c.4575C>T p.P1525= | Silent (SNP) | VAF 19/201 reads (9%) | catalogued as rs374902997, COSV55869437, COSV55881921; called by muse, mutect2, varscan2
- PCLO | c.9564C>T p.S3188= | Silent (SNP) | VAF 26/210 reads (12%) | catalogued as rs765936627, COSV61661336; called by muse, mutect2, varscan2
- DPP6 | c.-206G>C | 5'UTR (SNP) | VAF 19/165 reads (12%) | catalogued as rs566203231; called by muse, mutect2, varscan2
- HCFC2 | c.*2761T>A | 3'UTR (SNP) | VAF 19/168 reads (11%) | called by muse, mutect2, varscan2
